TCGA case TCGA-24-2027 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/219f54ef-4235-482d-b799-f2fa9930105c

Demographics
Sex at birth: female; Race: white; Age at index: 51 years; Vital status: Dead; Days to death: 3,337 days (9.1 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 51.6 years (18,835 days); Year of diagnosis: 1995; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Days to treatment end: 258 days; Number of cycles: 12; Treatment dose: 9,838 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Days to treatment end: 258 days; Number of cycles: 12; Treatment dose: 3,724 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 624 days (1.7 years); Days to treatment end: 784 days (2.1 years); Number of cycles: 7; Treatment dose: 3,411 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 624 days (1.7 years); Days to treatment end: 784 days (2.1 years); Number of cycles: 7; Treatment dose: 88 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 624 days (1.7 years); Days to treatment end: 784 days (2.1 years); Number of cycles: 7; Treatment dose: 1,860 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 1,614 days (4.4 years); Days to treatment end: 1,985 days (5.4 years); Number of cycles: 17; Treatment dose: 151 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 2,048 days (5.6 years); Days to treatment end: 2,216 days (6.1 years); Number of cycles: 20; Treatment dose: 1,747 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 2,400 days (6.6 years); Days to treatment end: 2,540 days (7.0 years); Number of cycles: 6; Treatment dose: 400 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 2,577 days (7.1 years); Days to treatment end: 2,591 days (7.1 years); Number of cycles: 1; Treatment dose: 83 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 2,577 days (7.1 years); Days to treatment end: 2,591 days (7.1 years); Number of cycles: 1; Treatment dose: 1,992 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Progressive Disease; Days to treatment start: 2,602 days (7.1 years); Days to treatment end: 2,745 days (7.5 years); Number of cycles: 7; Treatment dose: 311 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 2,759 days (7.6 years); Days to treatment end: 2,951 days (8.1 years); Number of cycles: 18; Treatment dose: 1,108 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 2,982 days (8.2 years); Days to treatment end: 3,154 days (8.6 years); Number of cycles: 6; Treatment dose: 67 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 3,168 days (8.7 years); Days to treatment end: 3,273 days (9.0 years); Number of cycles: 6; Treatment dose: 1,052 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 53.3 years (19,452 days); Days to diagnosis: 617 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 617 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 617 days (1.7 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 3,337 days (9.1 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Other.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-2027-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.6; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-24-2027-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 7; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-24-2027-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-24-2027-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 8: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 12: Pharmaceutical therapy drug name: Navelbine; Therapy regimen: Progression.
- Drug treatment 13: Pharmaceutical therapy drug name: Doxil.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,337 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 3,337 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 617 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-24-2027-01): tumor purity 0.9, ploidy 1.85, whole-genome doublings 0 (call status: legacy_call).
